Somatic mutation profile of tumor specimen 0DDNCN from CCDI case PBBNWE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neurofibromatosis, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.8 years (6,130 days).
Specimen 0DDNCN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f300697-6609-4f1c-a5e9-8b2adaa76acb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDNCO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/152326cc-c7b4-4a1e-9b6a-2194bad85fb3

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NBEA | c.3984G>A p.M1328I | Missense Mutation (SNP) | VAF 108/1026 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.046); catalogued as rs1341386598; called by muse, varscan2
- UBTF | c.1231G>A p.V411M | Missense Mutation (SNP) | VAF 124/570 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.69); catalogued as rs752694009; called by muse, varscan2
- PCDHB1 | c.266A>C p.K89T | Missense Mutation (SNP) | VAF 114/328 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); called by muse, varscan2
